Somatic mutation profile of tumor specimen TCGA-EJ-5510-01A (aliquot TCGA-EJ-5510-01A-01D-1576-08) from TCGA case TCGA-EJ-5510, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.0 years (17,895 days).
Specimen TCGA-EJ-5510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fa68db6-f7da-4d91-a5e6-0f981849b1d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5510-10A (Blood Derived Normal), aliquot TCGA-EJ-5510-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39859d92-3546-4f9c-9caf-20b0510c241f

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.3385G>A p.G1129R (on ENST00000341947 / NM_080680.3; = p.G1022R on NM_080679.2) | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550153707, COSV59493862; ClinVar: likely pathogenic; called by muse, mutect2
- MED12 | c.3670C>T p.L1224F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519912, COSV61329632, COSV61332429; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.4387C>T p.Q1463* | Nonsense Mutation (SNP) | VAF 38/208 reads (18%) | catalogued as COSV55788743; called by muse, mutect2, varscan2
- ADGRL2 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54684085; called by muse, mutect2, varscan2
- ADRA2A | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529651; called by muse, mutect2, varscan2
- CARD16 | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 110/618 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65213357; called by muse, mutect2, varscan2
- CCDC7 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.998); catalogued as COSV53234038; called by muse, mutect2, varscan2
- CCDC7 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53234065; called by muse, mutect2, varscan2
- DYRK1A | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV58296556; called by muse, mutect2, varscan2
- FHDC1 | c.3283C>T p.P1095S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs568498816, COSV99471135; called by muse, varscan2
- FREM2 | c.5677G>A p.V1893I | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs548177107, COSV54832643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT78 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs754113390, COSV58852337; called by muse, mutect2, varscan2
- MCM6 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.274); catalogued as rs200697022; called by muse, mutect2, varscan2
- PGAP4 | c.186C>A p.S62R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV66388275; called by muse, mutect2, varscan2
- SHANK2 | c.5429A>G p.N1810S | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53615106; called by muse, mutect2, varscan2
- TEKT1 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.152); catalogued as COSV58624550; called by muse, mutect2, varscan2
- TM9SF2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV64507367; called by muse, mutect2, varscan2
- ZCCHC12 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV59572749; called by muse, mutect2, varscan2
- GNPNAT1 | c.421_422del p.L141Yfs*15 | Frame Shift Del (DEL) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- SAC3D1 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); called by muse, mutect2
- ADAMTS20 | c.4467T>C p.C1489= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV67137705; called by muse, mutect2
- API5 | c.669A>C p.L223= | Silent (SNP) | VAF 36/210 reads (17%) | catalogued as COSV66634708; called by muse, mutect2, varscan2
- FAM47C | c.1302C>T p.R434= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs782274990, COSV63724500, COSV63727604; called by muse, mutect2, varscan2
- NEK7 | c.336A>G p.E112= | Silent (SNP) | VAF 27/254 reads (11%) | catalogued as COSV66315930; called by muse, mutect2, varscan2
- RPLP0 | c.765G>A p.T255= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs777166855, COSV56113574; called by muse, mutect2, varscan2
- BTN2A3P | n.1118A>G | RNA (SNP) | VAF 72/324 reads (22%) | called by muse, mutect2, varscan2
